TCGA case TCGA-SR-A6MR — Pheochromocytoma and Paraganglioma (TCGA-PCPG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Paragangliomas and Glomus Tumors; Primary site: Retroperitoneum and peritoneum; Tissue source site: Tufts Medical Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5a36b7af-70c6-4a08-84ac-01ef15739337

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 41 years; Vital status: Alive.

Diagnoses (3)
1. Extra-adrenal paraganglioma, malignant (the primary disease): ICD-O-3 morphology code: 8693/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 41.0 years (14,991 days); Year of diagnosis: 2007; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 2,409 days (6.6 years); Cancer detection method: Screening.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 1.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Pheochromocytoma, NOS: ICD-O-3 morphology code: 8700/0; Tissue or organ of origin: Adrenal gland, NOS; Laterality: Right; Classification of tumor: Prior primary; Age at diagnosis: 34.9 years (12,758 days); Days to diagnosis: -2,233 days (-6.1 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -2,224 days (-6.1 years); Treatment anatomic sites: Adrenal.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Subsequent primary of the retroperitoneum (histology not recorded by GDC). Age at diagnosis: 43.6 years (15,919 days); Days to diagnosis: 928 days (2.5 years); Prior treatment: Yes.

Follow-up (4 entries)
- Day 0 (prior to diagnosis): History of tumor: Yes; History of tumor type: Phenochromocytoma or Paraganglioma.
- Days to follow up: 2,020 days (5.5 years); Disease response: With Tumor.
- Days to follow up: 2,409 days (6.6 years); Disease response: With Tumor.
- Karnofsky performance status: 90; ECOG performance status: 1; Timepoint: Other.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-SR-A6MR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 30 mg.
  Slide TCGA-SR-A6MR-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-SR-A6MR-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-SR-A6MR-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History pheo or para include benign: Yes; History pheo or para anatomic site: Right adrenal; History neoadjuvant treatment: No; Tumor status: With tumor; Treatment outcome first course: Stable Disease; New tumor event diagnosis indicator: Yes.
- Primary pathology: Submitted tumor site: Extra-adrenal Site; Site of primary tumor other: portocaval paraganglia; Related tumors outside adrenal glands: Multiple tumors outside the adrenal glands; Histologic diagnosis: Paraganglioma; Disease detected on screening: Yes; Ct scan preop results: Yes; Lymph nodes examined: Yes.
- New tumor event: New tumor event type: New Primary Tumor; New tumor event diagnosis confirmed by: Imaging.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; New tumor event diagnosis indicator: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Adrenal gland; Other malignancy histological type: pheochromocytoma.
- Other malignancy form, Surgery: Other malignancy surgery type: adrenalectomy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,409 days; disease-specific survival: no event (censored), 2,409 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 928 days.
